MMRF case MMRF_2631 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/331e45d2-5001-42db-918b-8585b76fa575

Demographics
Sex at birth: male; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.8 years (23,294 days); ISS stage: II; Days to last known disease status: 617 days (1.7 years); Days to last follow up: 617 days (1.7 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 159 days; Days to treatment end: 159 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day -6, day 617.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Creatinine 91.9 µmol/L.
- Absolute Neutrophil 7.3 ×10⁹/L.
- Beta 2 Microglobulin 3.6 µg/mL.
- Serum Free Immunoglobulin Light Chain, Kappa 1.19 mg/dL.
- Platelets 184 ×10⁹/L.
- Hemoglobin 9.24 mmol/L.
- Calcium 2.36 mmol/L.
- Albumin 38.6 g/L.
- Serum Free Immunoglobulin Light Chain, Lambda 4.77 mg/dL.
- Lactate Dehydrogenase 5.57 µkat/L.

Other clinical attributes
- Day -6: Weight: 84 kg; Height: 178 cm.

Biospecimens (2 samples)
- Sample MMRF_2631_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_2631_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
